Somatic mutation profile of tumor specimen TCGA-2Y-A9H0-01A (aliquot TCGA-2Y-A9H0-01A-11D-A382-10) from TCGA case TCGA-2Y-A9H0, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 49.6 years (18,109 days).
Specimen TCGA-2Y-A9H0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7183a04-e471-4137-af1a-fbf104fa2b79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9H0-10A (Blood Derived Normal), aliquot TCGA-2Y-A9H0-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae5537c3-dd96-4675-831a-b9a242144782

The open-access MAF lists 83 somatic variants for this specimen: 66 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 14, Nonsense Mutation 4, Splice Site 3, Frame Shift Ins 2, Frame Shift Del 2, 5'Flank 1, 3'UTR 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5524A>T p.T1842S (on ENST00000272895 / NM_173076.3; = p.T1524S on NM_015657.3) | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV99791007; called by muse, mutect2, varscan2
- ABCA9 | c.1929A>T p.E643D | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100383312; called by muse, mutect2, varscan2
- ADAM7 | c.1493A>G p.Y498C | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51540674, COSV99444461; called by muse, mutect2, varscan2
- AJM1 | c.2330C>G p.P777R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99915779; called by muse, mutect2, varscan2
- ANKRD30A | c.2891T>A p.I964N (on ENST00000611781; = p.I908N on NM_052997.2) | Missense Mutation (SNP) | VAF 159/398 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV100654041; called by muse, mutect2
- AP5Z1 | c.1174C>A p.L392M | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100804190; called by muse, mutect2, varscan2
- APOBR | c.459C>A p.S153R | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.362); catalogued as COSV100112715; called by muse, mutect2, varscan2
- CFAP58 | c.1538C>G p.T513R | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as rs1226550846, COSV100866130; called by muse, mutect2, varscan2
- CHMP1B | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99303920; called by muse, mutect2, varscan2
- CNTN1 | c.2725C>G p.P909A | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100751668; called by muse, mutect2, varscan2
- CPA1 | c.80G>C p.R27P | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547564304, CM139197, COSV50568895, COSV99163292; called by muse, mutect2, varscan2
- DAAM1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.099); catalogued as COSV100658563; called by muse, mutect2, varscan2
- DAZAP1 | c.701-2A>C p.X234_splice | Splice Site (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99245383; called by muse, mutect2, varscan2
- DCN | c.539A>T p.E180V | Missense Mutation (SNP) | VAF 114/176 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99272457; called by muse, mutect2, varscan2
- DNAAF5 | c.1025-2A>G p.X342_splice | Splice Site (SNP) | VAF 67/174 reads (39%) | catalogued as COSV99860066; called by muse, mutect2, varscan2
- DPP8 | c.1742G>C p.C581S (on ENST00000341861 / NM_001320875.2; = p.C565S on NM_017743.6) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.3); catalogued as COSV100202487; called by muse, mutect2, varscan2
- DPPA4 | c.466A>C p.T156P | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.154); catalogued as COSV100169568; called by muse, mutect2, varscan2
- DYNC1I1 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as rs748814410, COSV61455179; called by muse, mutect2, varscan2
- ECEL1 | c.1810G>A p.G604R | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745378093, COSV100458848; called by muse, mutect2, varscan2
- EEF1G | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100240509; called by muse, mutect2, varscan2
- FAM177B | c.286A>C p.T96P | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as COSV100680430; called by muse, mutect2, varscan2
- FBN1 | c.3472G>T p.E1158* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100355890; called by muse, mutect2
- GNAT3 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs879833721, COSV101242412, COSV68069709; called by muse, mutect2, varscan2
- GPAT2 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV100853325; called by mutect2, varscan2
- GRAMD1B | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100454979; called by muse, mutect2, varscan2
- HCN4 | c.1688T>A p.M563K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99983979; called by muse, mutect2, varscan2
- ING5 | c.633G>A p.W211* | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | catalogued as rs1287786813, COSV100546016; called by muse, mutect2, varscan2
- KLHDC7B | c.523A>T p.K175* (on ENST00000395676; = p.K816* on NM_138433.5) | Nonsense Mutation (SNP) | VAF 42/51 reads (82%) | catalogued as COSV101192969; called by muse, mutect2, varscan2
- LMLN | c.1924C>G p.L642V | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.967); catalogued as COSV57598131; called by muse, mutect2, varscan2
- LTK | c.2256-1G>C p.X752_splice | Splice Site (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99541074; called by muse, mutect2, varscan2
- MARCHF7 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99373926; called by muse, mutect2, varscan2
- MTHFD2 | c.778A>C p.I260L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as COSV99903149; called by muse, mutect2, varscan2
- MYH2 | c.941C>G p.P314R | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.4); PolyPhen benign (0.417); catalogued as COSV99820566; called by muse, mutect2, varscan2
- MYO16 | c.4135G>T p.A1379S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.048); catalogued as COSV100696909, COSV62750742; called by muse, mutect2, varscan2
- MYO1H | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.343); catalogued as rs749053878, COSV100183795; called by muse, mutect2, varscan2
- NAV3 | c.5740C>A p.R1914S (on ENST00000397909 / NM_001024383.2; = p.R1892S on NM_014903.6) | Missense Mutation (SNP) | VAF 144/222 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99893403; called by muse, mutect2, varscan2
- NCOA6 | c.5702C>G p.A1901G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100750180; called by muse, mutect2, varscan2
- NUP214 | c.5482A>G p.T1828A | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as rs777422483, COSV100845354; called by muse, mutect2, varscan2
- OR2V2 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100080192; called by muse, mutect2, varscan2
- PDZD8 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 52/114 reads (46%) | catalogued as COSV100559574; called by muse, mutect2, varscan2
- PLA2R1 | c.1696A>C p.S566R | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.465); catalogued as COSV99323229; called by muse, mutect2, varscan2
- PLEKHG7 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1385307644, COSV100760146; called by muse, mutect2, varscan2
- PPFIA2 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 118/180 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1260047014, COSV100334448; called by muse, mutect2, varscan2
- PRCC | c.1290G>T p.L430F | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV99618817; called by muse, mutect2, varscan2
- PSMB2 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100951602; called by muse, mutect2
- PTGDR | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.141); catalogued as COSV100035680; called by muse, mutect2, varscan2
- PTPRC | c.1914G>T p.L638F | Missense Mutation (SNP) | VAF 124/197 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100722852; called by muse, mutect2, varscan2
- PTPRM | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100158908; called by muse, mutect2, varscan2
- PURA | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100495765; called by muse, mutect2, varscan2
- RBP3 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs782227889; called by muse, mutect2, varscan2
- RYR1 | c.3236C>A p.S1079Y | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100616369, COSV62090244; called by muse, mutect2, varscan2
- SDK1 | c.1958G>C p.G653A | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.203); catalogued as COSV101269614; called by muse, mutect2, varscan2
- SFPQ | c.1737G>A p.M579I | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100599475; called by muse, mutect2, varscan2
- SH3TC1 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV55287780, COSV99795135; called by muse, mutect2, varscan2
- SLC13A2 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.02); catalogued as COSV100120408; called by muse, mutect2, varscan2
- SLC39A12 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66197489; called by muse, mutect2, varscan2
- SNRPD3 | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.292); catalogued as COSV99307548; called by muse, mutect2, varscan2
- SVIL | c.3865C>T p.L1289F (on ENST00000355867 / NM_021738.3; = p.L863F on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100881429; called by muse, mutect2, varscan2
- TWSG1 | c.671A>T p.*224Lext*10 | Nonstop Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100039455; called by muse, mutect2, varscan2
- UNC13B | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); catalogued as COSV101036956; called by muse, mutect2, varscan2
- WSB1 | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 75/119 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV99286084; called by muse, mutect2, varscan2
- ZNF493 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100828796; called by muse, mutect2, varscan2
- AP3M2 | c.366_373del p.L123Rfs*6 | Frame Shift Del (DEL) | VAF 36/97 reads (37%) | called by mutect2, pindel, varscan2
- CNTN2 | c.160del p.E54Rfs*22 | Frame Shift Del (DEL) | VAF 154/291 reads (53%) | called by mutect2, pindel, varscan2
- COL16A1 | c.746dup p.E250Rfs*13 | Frame Shift Ins (INS) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- FAM114A1 | c.1295dup p.E433Gfs*6 | Frame Shift Ins (INS) | VAF 72/214 reads (34%) | called by mutect2, pindel, varscan2
- A2ML1 | c.3360T>A p.G1120= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100229202; called by muse, mutect2, varscan2
- ASMT | c.81C>T p.A27= | Silent (SNP) | VAF 107/123 reads (87%) | catalogued as rs753071932, COSV101172498; called by muse, mutect2, varscan2
- CAMTA1 | c.2451A>G p.A817= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV100351528; called by muse, mutect2, varscan2
- CDH7 | c.2085A>T p.R695= | Silent (SNP) | VAF 73/181 reads (40%) | catalogued as COSV100542841; called by muse, mutect2, varscan2
- COBL | c.2184C>T p.T728= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs772330553, COSV54344998; called by muse, mutect2, varscan2
- CSMD1 | c.3769C>T p.L1257= (on ENST00000520002; = p.L1256= on NM_033225.6) | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as rs779267560, COSV100152876, COSV59361676; called by muse, mutect2, varscan2
- CSNK1A1L | c.264A>G p.L88= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs1436099085, COSV101131114; called by muse, mutect2, varscan2
- EPAS1 | c.492A>T p.T164= | Silent (SNP) | VAF 90/217 reads (41%) | catalogued as COSV99763388; called by muse, mutect2, varscan2
- FAM131A | c.831G>T p.S277= (on ENST00000310585; = p.S308= on NM_144635.5) | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as COSV99658759; called by muse, mutect2, varscan2
- KCNH5 | c.264C>T p.Y88= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs373008977; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR2Y1 | c.171A>G p.T57= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV57136169; called by muse, mutect2, varscan2
- SLC24A5 | c.840A>C p.I280= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV99981903; called by muse, mutect2, varscan2
- TNFRSF1A | c.1242C>T p.R414= | Silent (SNP) | VAF 113/272 reads (42%) | catalogued as COSV99164610; called by muse, mutect2, varscan2
- VDAC2 | c.438A>G p.G146= | Silent (SNP) | VAF 102/239 reads (43%) | catalogued as COSV100041029; called by muse, mutect2, varscan2
- CTSC | c.318+6753T>A | Intron (SNP) | VAF 39/91 reads (43%) | catalogued as COSV99910839; called by muse, mutect2, varscan2
- DALRD3 | chr3:49020234 C>G | 5'Flank (SNP) | VAF 34/98 reads (35%) | catalogued as COSV100455112; called by muse, mutect2, varscan2
- NAALADL1 | c.*1C>T | 3'UTR (SNP) | VAF 19/50 reads (38%) | catalogued as rs757027806, COSV100101262; called by muse, mutect2, varscan2
